Surgical pathology report (de-identified scan), TCGA case TCGA-28-2501, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-2501-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

DIAGNOSIS:

A. BRAIN, RIGHT FRONTOPIRIETAL, BIOPSY, NCI #1:

- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 10% of tumor cellularity

B. BRAIN, RIGHT FRONTOPIRIETAL, BIOPSY, NCI #2:

- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 80% of tumor cellularity

C. BRAIN, RIGHT FRONTOPIRIETAL, BIOPSY, NCI #3:

- Glioblastoma multiforme, WHO grade IV
- 10% of tumor necrosis
- 60% of tumor cellularity

D. BRAIN, RIGHT FRONTOPIRIETAL, BIOPSY, NCI #4:

- Glioblastoma multiforme, WHO grade IV
- 10% of tumor necrosis
- 80% of tumor cellularity

E. BRAIN, RIGHT FRONTOPIRIETAL, BIOPSY, NCI #5:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 15% of tumor cellularity

F, G. BRAIN, RIGHT FRONTOPIRIETAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

H. SKULL, SURGICAL HARDWARE REMOVAL:

- Explanted hardware (screws)

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to Temodar. Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to Temodar.

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors.

Source: NCI Genomic Data Commons file af691341-7ca6-49df-b077-2594247210ef (TCGA-28-2501.84170183-CB41-4637-BB8F-AA9DD894AA9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).